TCGA case TCGA-BA-6873 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of tongue; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bf6b931e-cb2e-4cc0-b603-e9fc71fdc509

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 28 years; Vital status: Alive.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C02.9; Tissue or organ of origin: Tongue, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 28.8 years (10,512 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N2b; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T4a; AJCC pathologic N: N2b; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 122 days.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: Gross Extension; Lymph nodes positive: 3; Lymph nodes tested: 48; Lymphatic invasion present: Yes; Margin status: Indeterminate; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 72 days; Days to treatment end: 118 days; Number of cycles: 3; Treatment dose: 640 mg; Prescribed dose: 100; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 72 days; Days to treatment end: 122 days; Treatment dose: 4,600 cGy; Course number: 1; Treatment anatomic sites: Locoregional Site.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Tongue, NOS. Age at diagnosis: 29.0 years (10,578 days); Days to diagnosis: 66 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS to Locoregional Site, for recurrent disease.

Follow-up (3 entries)
- Day 66 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Tongue, NOS; Days to recurrence: 66 days.
- Days to follow up: 122 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 113.

Exposures
- Alcohol history: No; Alcohol drinks per day: 0; Alcohol days per week: 0.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 1; Tobacco smoking onset year: 2001.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BA-6873-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.6; Shortest dimension: 0.2.
  Slide TCGA-BA-6873-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 18; Percent necrosis: 2; Percent stromal cells: 10; Percent lymphocyte infiltration: 7.
- Sample TCGA-BA-6873-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BA-6873-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Anatomic organ subdivision: Oral Tongue; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Close; Lymphovascular invasion: Yes; Tobacco smoking history indicator: 2; Alcohol history documented: Yes; Alcohol consumption frequency: 0.
- Drug treatment: Regimen number: 1; Therapy regimen: Progression.
- Drug treatment, Route of administrations: Route of administration: IV.
- Follow-up form: Lost to follow-up: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event site: Oral Cavity; New tumor event site other: L Tongue and bilat. neck LNs.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 122 days; disease-specific survival: no event (censored), 122 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 66 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BA-6873-01A-11D-1869-01): tumor purity 0.41, ploidy 3.66, whole-genome doublings 1.
